Somatic mutation profile of tumor specimen TCGA-HT-7879-01A (aliquot TCGA-HT-7879-01A-11D-2395-08) from TCGA case TCGA-HT-7879, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 31.8 years (11,622 days).
Specimen TCGA-HT-7879-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a560706-af00-4c11-b7ab-005e73618763.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HT-7879-10A (Blood Derived Normal), aliquot TCGA-HT-7879-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c0bd03ad-d3a5-441d-bdbd-70b983357a75

The open-access MAF lists 17 somatic variants for this specimen: 15 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Del 2, Silent 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 18/90 reads (20%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.578A>T p.H193L | Missense Mutation (SNP) | VAF 23/68 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- CACNA1H | c.5200G>A p.G1734S | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61987762, COSV62000598; called by muse, mutect2, varscan2
- CDC20B | c.661G>A p.V221M | Missense Mutation (SNP) | VAF 36/93 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.293); catalogued as COSV57055754; called by muse, mutect2, varscan2
- EWSR1 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 52/152 reads (34%) | catalogued as COSV58426549; called by muse, mutect2, varscan2
- GAD2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 95/203 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs748346267, COSV52158050, COSV52165260; called by muse, mutect2, varscan2
- MLLT1 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.351); catalogued as COSV53132483; called by muse, mutect2
- MZT2A | c.346G>C p.G116R | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.542); catalogued as COSV58312021, COSV58312985; called by muse, mutect2
- OGT | c.588T>G p.N196K | Missense Mutation (SNP) | VAF 76/87 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200109331, COSV65482199; called by muse, mutect2, varscan2
- PKHD1 | c.3244A>G p.I1082V | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV61890276; called by muse, mutect2, varscan2
- PTBP3 | c.1433A>G p.H478R | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57586160; called by muse, mutect2, varscan2
- SCGN | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.231); catalogued as COSV100618721; called by muse, varscan2
- TBC1D9 | c.35A>G p.N12S | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.043); catalogued as rs759253011, COSV71308361; called by muse, mutect2, varscan2
- ATRX | c.2747del p.A916Vfs*54 | Frame Shift Del (DEL) | VAF 107/179 reads (60%) | called by mutect2, pindel, varscan2
- TP53 | c.787_788del p.N263Sfs*8 | Frame Shift Del (DEL) | VAF 16/42 reads (38%) | called by mutect2, pindel, varscan2
- STAM2 | c.438A>G p.A146= | Silent (SNP) | VAF 54/126 reads (43%) | catalogued as COSV55733393; called by muse, mutect2, varscan2
- CACNB2 | c.214-828T>C | Intron (SNP) | VAF 38/86 reads (44%) | catalogued as rs760386247, COSV99994204; called by muse, mutect2, varscan2
